Somatic mutation profile of tumor specimen TCGA-BB-4227-01A (aliquot TCGA-BB-4227-01A-01D-1870-08) from TCGA case TCGA-BB-4227, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Hypopharynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 66.6 years (24,322 days).
Specimen TCGA-BB-4227-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bb3f9e0d-dd75-42a4-9260-a07c59c0edf2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BB-4227-10A (Blood Derived Normal), aliquot TCGA-BB-4227-10A-01D-1870-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/288cde90-7bcf-4399-9e81-29c815d57be4

The open-access MAF lists 282 somatic variants for this specimen: 192 protein-altering or splice-affecting, 86 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 165, Silent 86, Nonsense Mutation 18, Frame Shift Del 4, Intron 3, Splice Site 2, Splice Region 1, In Frame Del 1, 3'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 40/48 reads (83%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA7 | c.4201C>T p.Q1401* | Nonsense Mutation (SNP) | VAF 7/29 reads (24%) | catalogued as rs1167601179, COSV99566596; called by muse, mutect2, varscan2
- ABCB11 | c.3155T>C p.F1052S | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1373646294, COSV99792967; called by muse, mutect2, varscan2
- ABCB11 | c.2782C>G p.R928G | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as CM072812, COSV99792970, COSV99793384; called by muse, mutect2, varscan2
- ACAD11 | c.1099G>C p.D367H | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.382); catalogued as COSV99392610; called by muse, mutect2, varscan2
- ACSM1 | c.367G>C p.E123Q | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99533379; called by muse, mutect2, varscan2
- ADGRG6 | c.441C>G p.I147M | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.264); catalogued as COSV99748531; called by muse, mutect2, varscan2
- AL645922.1 | c.2338T>A p.S780T | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100191460; called by muse, mutect2, varscan2
- ANAPC5 | c.1798G>A p.A600T | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as rs780247790, COSV99946449; called by muse, mutect2, varscan2
- ANKRD11 | c.3696G>C p.K1232N | Missense Mutation (SNP) | VAF 59/119 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.638); catalogued as COSV99970474; called by muse, varscan2
- ANKRD11 | c.3545G>A p.R1182K | Missense Mutation (SNP) | VAF 62/150 reads (41%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV56358342; called by muse, varscan2
- AP4E1 | c.1147G>C p.D383H | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99957147; called by muse, mutect2, varscan2
- APBB1 | c.1652T>C p.V551A | Missense Mutation (SNP) | VAF 12/271 reads (4%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.583); catalogued as COSV100194293; called by muse, mutect2
- APOB | c.7424C>A p.A2475D | Missense Mutation (SNP) | VAF 29/141 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV99267747; called by muse, mutect2, varscan2
- ARAP2 | c.3447C>G p.I1149M | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV100395203; called by muse, mutect2, varscan2
- ARHGEF9 | c.553C>G p.L185V | Missense Mutation (SNP) | VAF 18/21 reads (86%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.863); catalogued as COSV99492358; called by muse, mutect2, varscan2
- ARMC4 | c.2761C>T p.H921Y | Missense Mutation (SNP) | VAF 56/158 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.418); catalogued as COSV59467087; called by muse, varscan2
- ARMC4 | c.2633C>A p.S878Y | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100537369; called by muse, mutect2, varscan2
- ASAP3 | c.2210C>T p.A737V | Missense Mutation (SNP) | VAF 91/203 reads (45%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100369642; called by muse, mutect2, varscan2
- ATP10B | c.1639G>C p.D547H | Missense Mutation (SNP) | VAF 52/128 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100515671; called by muse, mutect2, varscan2
- ATP10B | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV100469718; called by muse, mutect2, varscan2
- AUTS2 | c.743-1G>T p.X248_splice | Splice Site (SNP) | VAF 50/298 reads (17%) | catalogued as COSV100719474; called by muse, mutect2, varscan2
- BAIAP3 | c.322G>C p.E108Q | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); catalogued as rs770795319, COSV60979562; called by muse, mutect2, varscan2
- BCAN | c.2167C>G p.L723V | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as COSV100228169; called by muse, mutect2, varscan2
- BCHE | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746209182, COSV100012948; called by muse, mutect2, varscan2
- BIRC2 | c.1069G>C p.E357Q | Missense Mutation (SNP) | VAF 9/220 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.214); catalogued as COSV99926902; called by muse, mutect2
- CAMSAP2 | c.2539G>C p.D847H (on ENST00000236925 / NM_001297707.2; = p.D836H on NM_203459.3) | Missense Mutation (SNP) | VAF 52/210 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.235); catalogued as COSV52666376, COSV99374238; called by muse, mutect2, varscan2
- CAPN12 | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.191); catalogued as COSV100185514; called by muse, mutect2, varscan2
- CCSAP | c.36G>A p.M12I | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as COSV99497527; called by muse, mutect2, varscan2
- CD101 | c.466C>G p.L156V | Missense Mutation (SNP) | VAF 43/125 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as COSV99870147; called by muse, mutect2, varscan2
- CEP250 | c.4663C>G p.L1555V | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.36); catalogued as COSV100699172; called by muse, mutect2, varscan2
- CEP250 | c.5173G>C p.E1725Q | Missense Mutation (SNP) | VAF 65/164 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1229892688, COSV100699173; called by muse, mutect2, varscan2
- CFAP54 | c.6703C>A p.P2235T | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.43); PolyPhen benign (0.169); catalogued as COSV100733310; called by muse, mutect2, varscan2
- CHD9 | c.1925G>C p.R642T | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV101272175, COSV68297866; called by muse, mutect2
- CHST13 | c.592A>T p.R198W | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100081367; called by muse, mutect2, varscan2
- COL9A2 | c.834G>C p.E278D | Missense Mutation (SNP) | VAF 55/146 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.057); catalogued as COSV101025771; called by muse, mutect2, varscan2
- CSDE1 | c.1013C>G p.S338* (on ENST00000358528 / NM_001007553.3; = p.S307* on NM_007158.6) | Nonsense Mutation (SNP) | VAF 15/141 reads (11%) | catalogued as COSV99795919; called by muse, mutect2, varscan2
- CSMD2 | c.1354G>C p.D452H | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV99594797; called by muse, mutect2, varscan2
- CYFIP1 | c.3052G>C p.E1018Q | Missense Mutation (SNP) | VAF 108/306 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100488745; called by muse, varscan2
- DBI | c.181G>A p.E61K (on ENST00000355857 / NM_001079862.3; = p.E78K on NM_020548.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100276039; called by muse, mutect2, varscan2
- DDX51 | c.622G>C p.D208H | Missense Mutation (SNP) | VAF 55/159 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.085); catalogued as COSV57961083; called by muse, mutect2, varscan2
- DLG2 | c.103G>C p.E35Q | Missense Mutation (SNP) | VAF 50/141 reads (35%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.548); catalogued as COSV101074026; called by muse, mutect2, varscan2
- DNAAF1 | c.1756G>A p.E586K | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as COSV100499779; called by muse, mutect2, varscan2
- DNAH2 | c.62G>A p.W21* | Nonsense Mutation (SNP) | VAF 21/44 reads (48%) | catalogued as COSV99318539; called by muse, mutect2, varscan2
- DPEP2 | c.609C>G p.F203L | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.421); catalogued as COSV99263221; called by muse, mutect2, varscan2
- DUS2 | c.1016C>T p.S339L | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs1483789765, COSV100732666; called by muse, mutect2, varscan2
- EIF2AK4 | c.2146G>A p.E716K | Missense Mutation (SNP) | VAF 42/113 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs781268719, COSV99775333; called by muse, mutect2, varscan2
- EML5 | c.3151G>A p.D1051N | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100716144; called by muse, mutect2, varscan2
- EPHB3 | c.2725C>T p.Q909* | Nonsense Mutation (SNP) | VAF 55/200 reads (28%) | catalogued as COSV100383271; called by muse, varscan2
- ERCC3 | c.1423G>C p.D475H | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.235); catalogued as COSV53425915, COSV99573647; called by muse, mutect2, varscan2
- EVI2B | c.401C>G p.S134C | Missense Mutation (SNP) | VAF 141/382 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.74); catalogued as COSV100445649; called by muse, mutect2, varscan2
- EXD3 | c.770A>G p.N257S | Missense Mutation (SNP) | VAF 35/41 reads (85%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.683); catalogued as rs753114880, COSV100573915; called by muse, mutect2, varscan2
- FAHD2B | c.932A>G p.N311S | Missense Mutation (SNP) | VAF 39/132 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs772182740, COSV99738270; called by muse, mutect2, varscan2
- FAM234B | c.1287C>T p.S429= | Splice Region (SNP) | VAF 44/123 reads (36%) | catalogued as COSV99545922; called by muse, mutect2, varscan2
- FAM83B | c.732C>A p.Y244* | Nonsense Mutation (SNP) | VAF 52/146 reads (36%) | catalogued as COSV100174962; called by muse, mutect2, varscan2
- FAM83E | c.1174G>A p.E392K | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.151); catalogued as rs267605566, COSV99572420, COSV99572493; called by muse, mutect2, varscan2
- FBLN2 | c.2581G>T p.E861* | Nonsense Mutation (SNP) | VAF 19/32 reads (59%) | catalogued as COSV99852556; called by muse, mutect2, varscan2
- FBXO4 | c.705C>G p.I235M | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.38); catalogued as COSV99715279; called by muse, mutect2, varscan2
- FLVCR1 | c.736C>G p.Q246E | Missense Mutation (SNP) | VAF 45/173 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as COSV100757935; called by muse, mutect2, varscan2
- FTO | c.91C>G p.L31V | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as COSV101151174, COSV67113449; called by muse, mutect2, varscan2
- GALNTL5 | c.1067C>G p.S356C | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101217944; called by muse, mutect2, varscan2
- GCNA | c.165G>C p.R55S | Missense Mutation (SNP) | VAF 39/49 reads (80%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); catalogued as rs773369953, COSV101032687; called by muse, mutect2, varscan2
- GFOD2 | c.891G>C p.Q297H | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as COSV99263707; called by muse, mutect2
- GPR39 | c.1039T>G p.S347A | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV100258487; called by muse, mutect2, varscan2
- GREB1 | c.1354C>A p.Q452K | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.647); catalogued as COSV99303713; called by muse, mutect2
- GRIA2 | c.1092G>C p.Q364H | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT tolerated (0.23); PolyPhen benign (0.014); catalogued as COSV99645851; called by muse, mutect2, varscan2
- GSTO1 | c.238G>A p.G80S | Missense Mutation (SNP) | VAF 46/113 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); catalogued as COSV100866947; called by muse, mutect2, varscan2
- GTPBP6 | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 43/56 reads (77%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs1292922184, COSV100397829; called by muse, mutect2, varscan2
- HACE1 | c.428G>A p.R143Q | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); catalogued as COSV53508454; called by muse, mutect2, varscan2
- HHIPL2 | c.25C>G p.L9V | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.003); catalogued as COSV100597065; called by muse, mutect2, varscan2
- HSPA2 | c.916G>C p.E306Q | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1384159734, COSV99905128; called by muse, mutect2, varscan2
- HTR1F | c.594G>C p.L198F | Missense Mutation (SNP) | VAF 56/74 reads (76%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100138293; called by muse, mutect2, varscan2
- HUNK | c.2031G>C p.Q677H | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV99528902; called by muse, mutect2, varscan2
- IFNGR1 | c.36G>C p.Q12H | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.84); catalogued as COSV100880527; called by muse, mutect2, varscan2
- IFT80 | c.1970C>G p.S657C | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.049); catalogued as COSV100425110; called by muse, mutect2, varscan2
- IGSF10 | c.7242G>C p.R2414S | Missense Mutation (SNP) | VAF 62/202 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as rs1293955180, COSV99193858; called by muse, mutect2, varscan2
- INPP5B | c.2174G>A p.R725K (on ENST00000373023; = p.R645K on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100886603; called by muse, mutect2, varscan2
- IQUB | c.1477del p.I493Sfs*15 | Frame Shift Del (DEL) | VAF 27/151 reads (18%) | catalogued as COSV61237565; called by mutect2, pindel, varscan2
- IRAK3 | c.365C>T p.P122L | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.462); catalogued as COSV54161384; called by muse, mutect2, varscan2
- ITCH | c.470C>T p.S157L | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV99393123; called by muse, mutect2, varscan2
- ITGB1BP2 | c.712C>T p.P238S | Missense Mutation (SNP) | VAF 51/66 reads (77%) | SIFT tolerated (1); PolyPhen benign (0.247); catalogued as COSV99339106; called by muse, mutect2, varscan2
- KCNH2 | c.2035C>T p.R679W | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs79624542, COSV51260593; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KHDC1 | c.520G>C p.E174Q (on ENST00000370384 / NM_001251874.2; = p.E101Q on NM_030568.5) | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.281); catalogued as COSV100001961, COSV57616393; called by muse, mutect2, varscan2
- KIAA0100 | c.1433C>T p.S478F | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764254287, COSV101197402; called by muse, mutect2, varscan2
- KLHL12 | c.1012G>A p.D338N | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.12); catalogued as COSV100935975; called by muse, mutect2, varscan2
- KRT39 | c.861C>G p.F287L | Missense Mutation (SNP) | VAF 294/3744 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV100842244; called by muse, mutect2
- KYNU | c.1042-1G>A p.X348_splice | Splice Site (SNP) | VAF 26/83 reads (31%) | catalogued as COSV99933968, COSV99934063; called by muse, mutect2, varscan2
- LATS1 | c.3068C>G p.S1023C | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV53601875; called by muse, mutect2, varscan2
- LATS1 | c.2509G>C p.D837H | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99486605; called by muse, mutect2, varscan2
- LPIN1 | c.2144A>G p.N715S | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99878144; called by muse, mutect2, varscan2
- LRIG1 | c.2608G>C p.E870Q | Missense Mutation (SNP) | VAF 63/104 reads (61%) | SIFT tolerated (0.07); PolyPhen benign (0.04); catalogued as COSV99834334; called by muse, mutect2, varscan2
- LRP6 | c.3034C>A p.L1012M | Missense Mutation (SNP) | VAF 106/272 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as COSV99744378; called by muse, mutect2, varscan2
- LRRC30 | c.251G>A p.R84Q | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.69); PolyPhen benign (0.194); catalogued as rs753691616, COSV101274445, COSV101274454; called by muse, mutect2, varscan2
- MAP3K19 | c.2394G>C p.Q798H | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.199); catalogued as COSV100208248; called by muse, mutect2, varscan2
- MAP3K7 | c.1570G>C p.E524Q (on ENST00000369329 / NM_145331.3; = p.E497Q on NM_003188.4) | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.113); catalogued as COSV65225608; called by muse, mutect2, varscan2
- MDGA2 | c.1978C>T p.Q660* (on ENST00000399232 / NM_001113498.2; = p.Q362* on NM_182830.4) | Nonsense Mutation (SNP) | VAF 45/117 reads (38%) | catalogued as rs1043297221, COSV100638306, COSV62083747; called by muse, mutect2, varscan2
- ME1 | c.1591C>T p.P531S | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63841828; called by muse, mutect2, varscan2
- MFAP3 | c.1060G>C p.D354H | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.525); catalogued as COSV100491734; called by muse, mutect2, varscan2
- MMP1 | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 16/197 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs745447214, COSV59510319, COSV59510620; called by muse, mutect2
- MMP27 | c.1479G>C p.K493N | Missense Mutation (SNP) | VAF 35/677 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV99498669; called by muse, mutect2
- MMP8 | c.420G>C p.W140C | Missense Mutation (SNP) | VAF 23/406 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99368866; called by muse, mutect2
- MTMR7 | c.208C>G p.L70V | Missense Mutation (SNP) | VAF 7/111 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.155); catalogued as COSV99472722; called by muse, mutect2
- MTRF1L | c.1120G>C p.E374Q | Missense Mutation (SNP) | VAF 57/160 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.28); catalogued as COSV100922494, COSV100922502; called by muse, mutect2, varscan2
- MYBPH | c.107C>G p.S36* | Nonsense Mutation (SNP) | VAF 104/352 reads (30%) | catalogued as COSV99704148; called by muse, mutect2, varscan2
- MYL9 | c.154G>T p.E52* | Nonsense Mutation (SNP) | VAF 17/99 reads (17%) | catalogued as rs1159077651, COSV99641164; called by muse, mutect2, varscan2
- MYPN | c.91G>T p.E31* | Nonsense Mutation (SNP) | VAF 14/93 reads (15%) | catalogued as COSV100590565; called by muse, mutect2, varscan2
- MZF1 | c.640G>C p.E214Q | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.056); catalogued as COSV53043269, COSV99285445; called by muse, mutect2, varscan2
- NLRC4 | c.356C>T p.P119L | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100707510; called by muse, varscan2
- NLRC4 | c.274C>G p.Q92E | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.05); catalogued as COSV100707511; called by muse, varscan2
- NOD1 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 44/58 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56114115; called by muse, mutect2, varscan2
- NPR1 | c.3090C>G p.F1030L | Missense Mutation (SNP) | VAF 50/182 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100902074; called by muse, mutect2, varscan2
- NRN1L | c.383C>G p.S128C | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.639); catalogued as COSV100197774; called by muse, mutect2, varscan2
- NUFIP2 | c.1702G>C p.E568Q | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.055); catalogued as COSV99837642; called by muse, mutect2, varscan2
- NYAP1 | c.1828G>A p.A610T | Missense Mutation (SNP) | VAF 40/147 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs778518564, COSV55720246; called by muse, mutect2, varscan2
- OCA2 | c.1558C>T p.L520F | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.151); catalogued as COSV100668598; called by muse, mutect2, varscan2
- ODF2L | c.1834G>C p.E612Q (on ENST00000317336; = p.E596Q on NM_020729.3) | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs149282656; called by muse, mutect2, varscan2
- OR1G1 | c.312C>A p.F104L | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.035); catalogued as COSV100187597, COSV61030038; called by muse, mutect2, varscan2
- OR2A14 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 83/236 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as rs746415046, COSV101376492; called by muse, mutect2, varscan2
- OR2B6 | c.523G>A p.D175N | Missense Mutation (SNP) | VAF 59/104 reads (57%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as COSV99773839; called by muse, mutect2, varscan2
- OR8H1 | c.142A>C p.I48L | Missense Mutation (SNP) | VAF 81/296 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100477335; called by muse, mutect2, varscan2
- PAK2 | c.1477G>C p.E493Q | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as COSV100506321, COSV59081153; called by muse, mutect2, varscan2
- PARP1 | c.1366G>C p.E456Q | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV100829041, COSV64689280; called by muse, mutect2, varscan2
- PARP10 | c.2718C>G p.F906L | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100478315; called by muse, mutect2
- PARS2 | c.622G>C p.D208H | Missense Mutation (SNP) | VAF 56/118 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1167861010, COSV100988335; called by muse, mutect2, varscan2
- PCDHGA4 | c.2153C>T p.S718L | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.009); catalogued as COSV99546170; called by muse, mutect2, varscan2
- PIAS3 | c.1039C>T p.Q347* | Nonsense Mutation (SNP) | VAF 93/172 reads (54%) | catalogued as COSV100566853; called by muse, mutect2, varscan2
- PLA2G15 | c.1112G>T p.C371F | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54720404, COSV99546820; called by muse, mutect2, varscan2
- PMS2 | c.1002C>G p.I334M | Missense Mutation (SNP) | VAF 39/76 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV56220817, COSV99764472, COSV99764539; called by muse, mutect2, varscan2
- PPP1R2 | c.606A>T p.L202F | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV100113424; called by muse, mutect2, varscan2
- PROK1 | c.300G>C p.L100F | Missense Mutation (SNP) | VAF 8/119 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99602656; called by muse, mutect2
- PRSS36 | c.1555G>C p.E519Q | Missense Mutation (SNP) | VAF 52/158 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.272); catalogued as rs1457718276, COSV99191323; called by muse, mutect2, varscan2
- PRX | c.1762C>G p.P588A | Missense Mutation (SNP) | VAF 96/314 reads (31%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.997); catalogued as COSV99398025; called by muse, mutect2, varscan2
- PTPMT1 | c.217G>C p.E73Q | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100442790, COSV100442953, COSV58596904; called by muse, mutect2, varscan2
- PUF60 | c.335C>G p.S112* | Nonsense Mutation (SNP) | VAF 94/377 reads (25%) | catalogued as COSV100513333; called by muse, mutect2, varscan2
- RBAK-RBAKDN | c.459G>C p.E153D | Missense Mutation (SNP) | VAF 39/162 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.451); catalogued as COSV101208280; called by muse, mutect2, varscan2
- RBBP8 | c.445C>G p.Q149E | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as COSV100507628; called by muse, mutect2, varscan2
- RFPL2 | c.238G>C p.E80Q | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as COSV50710767; called by muse, mutect2, varscan2
- RNF31 | c.406G>T p.E136* | Nonsense Mutation (SNP) | VAF 14/56 reads (25%) | catalogued as COSV53760426, COSV99396274; called by muse, mutect2, varscan2
- S100A4 | c.300G>C p.K100N | Missense Mutation (SNP) | VAF 90/399 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.395); catalogued as COSV100573031, COSV100573147; called by muse, mutect2, varscan2
- SEC24A | c.3172G>A p.E1058K | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as COSV101295044; called by muse, mutect2, varscan2
- SGIP1 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99392788; called by muse, varscan2
- SHANK2 | c.4186C>A p.L1396M | Missense Mutation (SNP) | VAF 42/564 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV99575908; called by muse, mutect2
- SLC17A3 | c.295C>T p.P99S | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV57760736; called by muse, mutect2, varscan2
- SPG11 | c.7015G>A p.E2339K | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as rs753466044, COSV99968720; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SRSF6 | c.41G>C p.R14P | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99719621, COSV99719830; called by muse, mutect2, varscan2
- SULF1 | c.1887G>C p.E629D | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated (1); PolyPhen probably damaging (0.954); catalogued as COSV99484261; called by muse, mutect2, varscan2
- SYNE2 | c.4611A>T p.L1537F | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100648429; called by muse, mutect2, varscan2
- TAFA3 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100721450; called by muse, mutect2, varscan2
- TAPBP | c.826C>T p.P276S | Missense Mutation (SNP) | VAF 109/263 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.431); catalogued as COSV101444969; called by muse, mutect2, varscan2
- TGFBRAP1 | c.1036C>T p.Q346* | Nonsense Mutation (SNP) | VAF 44/121 reads (36%) | catalogued as COSV99305439; called by muse, mutect2, varscan2
- TMEM236 | c.835C>T p.R279* | Nonsense Mutation (SNP) | VAF 149/402 reads (37%) | catalogued as rs1270327044; called by muse, mutect2, varscan2
- TMEM41A | c.579G>C p.L193F | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1333241129, COSV99407889; called by muse, mutect2, varscan2
- TNFAIP1 | c.5C>T p.S2L | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs782579729, COSV99880436; called by muse, mutect2, varscan2
- TOB2 | c.860G>C p.G287A | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV100548499; called by muse, mutect2, varscan2
- TOE1 | c.1012C>T p.R338W | Missense Mutation (SNP) | VAF 94/243 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs373495451; called by muse, mutect2, varscan2
- TOP3B | c.1267G>C p.D423H | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100592464, COSV64119454; called by muse, mutect2, varscan2
- TRIB1 | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 104/327 reads (32%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.464); catalogued as rs755466534, COSV100322596; called by muse, mutect2, varscan2
- TRIM43 | c.388G>C p.E130Q | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.465); catalogued as COSV55528559, COSV99720084; called by muse, mutect2, varscan2
- TRMT13 | c.1070G>T p.G357V | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100734562; called by muse, mutect2, varscan2
- TRPV1 | c.265G>C p.D89H | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.608); catalogued as COSV99440583; called by muse, varscan2
- TRPV1 | c.205G>C p.E69Q | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as COSV99440589; called by muse, varscan2
- TSHZ2 | c.1403G>C p.R468T | Missense Mutation (SNP) | VAF 63/168 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV100296712, COSV61588888; called by muse, mutect2, varscan2
- TSKS | c.1264G>C p.E422Q | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99883662; called by muse, mutect2, varscan2
- TSSK2 | c.158T>G p.V53G | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); catalogued as COSV99351195; called by muse, mutect2, varscan2
- TTC27 | c.1633G>C p.E545Q | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV100513519; called by muse, mutect2, varscan2
- TTC30A | c.1162G>C p.E388Q | Missense Mutation (SNP) | VAF 98/224 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.588); catalogued as COSV63101706; called by muse, mutect2, varscan2
- TTF1 | c.1991G>C p.R664T | Missense Mutation (SNP) | VAF 119/146 reads (82%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.498); catalogued as COSV100524853; called by muse, mutect2, varscan2
- TTN | c.102610G>A p.E34204K (on ENST00000591111; = p.E26780K on NM_003319.4) | Missense Mutation (SNP) | VAF 37/73 reads (51%) | PolyPhen benign (0.359); catalogued as COSV100628127; called by muse, mutect2, varscan2
- TTN | c.53410G>C p.E17804Q (on ENST00000591111; = p.E10380Q on NM_003319.4) | Missense Mutation (SNP) | VAF 62/182 reads (34%) | PolyPhen benign (0.099); catalogued as COSV100593351; called by muse, mutect2, varscan2
- TYK2 | c.2104G>C p.E702Q | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.034); catalogued as COSV99315346; called by muse, mutect2
- UBQLN3 | c.1421C>A p.P474H | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV100293951; called by muse, mutect2, varscan2
- UBXN1 | c.494G>A p.R165K | Missense Mutation (SNP) | VAF 56/171 reads (33%) | SIFT tolerated (0.92); PolyPhen benign (0.014); catalogued as rs1285212618, COSV99583388; called by muse, mutect2, varscan2
- USP11 | c.418G>C p.E140Q (on ENST00000218348; = p.E97Q on NM_001371072.1) | Missense Mutation (SNP) | VAF 17/22 reads (77%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV99511151; called by muse, mutect2, varscan2
- WDR35 | c.3254C>T p.S1085L (on ENST00000345530 / NM_001006657.2; = p.S1074L on NM_020779.4) | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99853484; called by muse, mutect2, varscan2
- WDR81 | c.4384G>A p.D1462N (on ENST00000409644 / NM_001163809.2; = p.D411N on NM_152348.4) | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.044); catalogued as COSV100489185; called by muse, mutect2, varscan2
- WDR81 | c.4522G>C p.E1508Q (on ENST00000409644 / NM_001163809.2; = p.E457Q on NM_152348.4) | Missense Mutation (SNP) | VAF 82/231 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.15); catalogued as COSV100489190, COSV58479431; called by muse, mutect2, varscan2
- WNT9A | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.67); catalogued as rs1213989309, COSV99688439; called by muse, mutect2, varscan2
- ZFHX3 | c.855C>G p.F285L | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as COSV99214518; called by muse, mutect2, varscan2
- ZHX3 | c.1986G>C p.E662D | Missense Mutation (SNP) | VAF 116/330 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV100476690; called by muse, mutect2, varscan2
- ZNF106 | c.526C>G p.H176D | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.688); catalogued as COSV99783129; called by muse, mutect2, varscan2
- ZNF284 | c.1413G>C p.L471F | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.995); catalogued as COSV101399081; called by muse, mutect2, varscan2
- ZNF318 | c.4520C>G p.S1507* | Nonsense Mutation (SNP) | VAF 22/70 reads (31%) | catalogued as COSV100546483; called by muse, mutect2, varscan2
- ZNF347 | c.2410A>G p.S804G | Missense Mutation (SNP) | VAF 73/184 reads (40%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1242028942, COSV100498415; called by muse, mutect2, varscan2
- ZNF394 | c.37G>A p.D13N | Missense Mutation (SNP) | VAF 61/117 reads (52%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.1); catalogued as rs1179433372, COSV100460357; called by muse, mutect2, varscan2
- ZNF559 | c.1094C>G p.S365C | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as COSV100416721; called by muse, mutect2, varscan2
- ZNF608 | c.4480C>G p.Q1494E | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV100102371; called by muse, mutect2, varscan2
- ZNF836 | c.1877C>G p.S626* | Nonsense Mutation (SNP) | VAF 81/231 reads (35%) | catalogued as COSV100441216; called by muse, mutect2, varscan2
- ATXN3L | c.585dup p.L196Ifs*8 | Frame Shift Ins (INS) | VAF 140/184 reads (76%) | called by mutect2, varscan2
- DLGAP4 | c.2865_2877del p.E955Dfs*78 (on ENST00000339266 / NM_001365621.1; = p.E952Dfs*78 on NM_014902.6) | Frame Shift Del (DEL) | VAF 22/63 reads (35%) | called by mutect2, pindel, varscan2
- HDGF | c.511_517delinsTT p.E171Lfs*4 | Frame Shift Del (DEL) | VAF 42/91 reads (46%) | called by pindel, varscan2*
- LYST | c.3783_3795del p.T1262* | Frame Shift Del (DEL) | VAF 23/153 reads (15%) | called by mutect2, pindel, varscan2
- PDE3A | c.1660_1679delinsGA p.T554_G560delinsD | In Frame Del (DEL) | VAF 33/161 reads (20%) | called by pindel, varscan2*
- ABL2 | c.568C>T p.L190= (on ENST00000502732 / NM_007314.4; = p.L175= on NM_005158.5) | Silent (SNP) | VAF 54/208 reads (26%) | catalogued as rs1230179108, COSV100772947, COSV61016912; called by muse, mutect2, varscan2
- ABRA | c.396G>A p.E132= | Silent (SNP) | VAF 71/245 reads (29%) | catalogued as COSV100357649; called by muse, mutect2, varscan2
- AC004922.1 | c.1638G>A p.G546= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as COSV53162528, COSV99403074; called by muse, mutect2, varscan2
- AC109583.1 | c.96G>C p.L32= | Silent (SNP) | VAF 7/9 reads (78%) | catalogued as COSV100167967, COSV59350404; called by muse, mutect2, varscan2
- ANK1 | c.4242C>G p.L1414= | Silent (SNP) | VAF 88/141 reads (62%) | catalogued as COSV99226683; called by muse, mutect2, varscan2
- ARFGEF1 | c.564C>T p.L188= | Silent (SNP) | VAF 47/156 reads (30%) | catalogued as rs750381594, COSV99144453; called by muse, mutect2, varscan2
- ARHGAP32 | c.2349G>A p.L783= (on ENST00000310343 / NM_001378025.1; = p.L434= on NM_014715.4) | Silent (SNP) | VAF 25/35 reads (71%) | catalogued as COSV100089155; called by muse, mutect2, varscan2
- C5orf51 | c.15C>G p.V5= | Silent (SNP) | VAF 27/74 reads (36%) | catalogued as rs780960330, COSV101069056; called by muse, mutect2, varscan2
- CABIN1 | c.3504G>A p.L1168= | Silent (SNP) | VAF 60/131 reads (46%) | catalogued as COSV99573938; called by muse, mutect2, varscan2
- CHRNA9 | c.918G>C p.T306= | Silent (SNP) | VAF 61/291 reads (21%) | catalogued as COSV100039099; called by muse, mutect2, varscan2
- CREB3L1 | c.1275C>G p.L425= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV99915292; called by muse, mutect2, varscan2
- DCBLD2 | c.2157C>T p.L719= | Silent (SNP) | VAF 73/354 reads (21%) | catalogued as rs1484677485, COSV54582973; called by muse, mutect2, varscan2
- DCST2 | c.975G>C p.L325= | Silent (SNP) | VAF 6/88 reads (7%) | catalogued as COSV55054207, COSV99792230; called by muse, mutect2
- DHX16 | c.2301C>G p.L767= | Silent (SNP) | VAF 88/205 reads (43%) | catalogued as COSV99528171; called by muse, mutect2, varscan2
- DHX34 | c.3021C>G p.V1007= | Silent (SNP) | VAF 33/80 reads (41%) | catalogued as rs1233833629, COSV100169869; called by muse, mutect2, varscan2
- DHX40 | c.1884C>T p.F628= | Silent (SNP) | VAF 5/86 reads (6%) | catalogued as COSV99233222; called by muse, mutect2
- EPHB3 | c.2406C>T p.I802= | Silent (SNP) | VAF 18/101 reads (18%) | catalogued as COSV100383270; called by muse, mutect2, varscan2
- ESRP1 | c.42C>T p.I14= | Silent (SNP) | VAF 10/107 reads (9%) | catalogued as rs369835294; called by muse, mutect2, varscan2
- FAM161A | c.786C>T p.I262= | Silent (SNP) | VAF 40/111 reads (36%) | catalogued as rs753308050, COSV56765238; called by muse, mutect2, varscan2
- FAM234A | c.939C>G p.L313= | Silent (SNP) | VAF 27/69 reads (39%) | catalogued as COSV100056434, COSV56997905; called by muse, mutect2, varscan2
- FNDC3B | c.2664G>A p.L888= | Silent (SNP) | VAF 37/141 reads (26%) | catalogued as COSV61044235; called by muse, mutect2, varscan2
- GALM | c.60G>A p.E20= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as COSV55373682; called by muse, mutect2, varscan2
- GCC2 | c.3843G>A p.L1281= | Silent (SNP) | VAF 54/135 reads (40%) | catalogued as COSV100565637; called by muse, mutect2, varscan2
- GOLGA3 | c.4155G>A p.P1385= | Silent (SNP) | VAF 32/87 reads (37%) | catalogued as rs779445245, COSV99212567; called by muse, mutect2, varscan2
- GRIN2A | c.3975C>T p.Y1325= | Silent (SNP) | VAF 61/155 reads (39%) | catalogued as rs545080350, COSV58022561; called by muse, mutect2, varscan2
- HBZ | c.54C>T p.I18= | Silent (SNP) | VAF 19/65 reads (29%) | catalogued as rs764421360, COSV99429460; called by muse, mutect2, varscan2
- HS3ST6 | c.981C>T p.F327= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as COSV53535417, COSV99562857; called by muse, mutect2, varscan2
- HSPBAP1 | c.729G>C p.L243= | Silent (SNP) | VAF 21/86 reads (24%) | catalogued as COSV100063718; called by muse, mutect2, varscan2
- IGSF10 | c.7002G>C p.L2334= | Silent (SNP) | VAF 71/272 reads (26%) | catalogued as COSV99193862; called by muse, mutect2, varscan2
- IL36B | c.432C>G p.L144= | Silent (SNP) | VAF 59/136 reads (43%) | catalogued as COSV99383098, COSV99383296; called by muse, mutect2, varscan2
- KCNC2 | c.225C>T p.G75= | Silent (SNP) | VAF 8/10 reads (80%) | catalogued as COSV100129779, COSV54374005; called by muse, varscan2
- KCNV1 | c.1230C>T p.F410= | Silent (SNP) | VAF 43/176 reads (24%) | catalogued as COSV99819416; called by muse, mutect2, varscan2
- KIAA1522 | c.1800C>G p.V600= (on ENST00000373480 / NM_001198972.2; = p.V659= on NM_020888.3) | Silent (SNP) | VAF 88/201 reads (44%) | catalogued as COSV53863525, COSV99615070; called by muse, mutect2, varscan2
- KLK2 | c.363C>G p.L121= | Silent (SNP) | VAF 26/71 reads (37%) | catalogued as COSV100320051; called by muse, mutect2, varscan2
- KRT27 | c.945G>A p.E315= | Silent (SNP) | VAF 33/348 reads (9%) | catalogued as COSV100053364; called by muse, mutect2
- LAMB1 | c.2007G>A p.P669= | Silent (SNP) | VAF 10/77 reads (13%) | catalogued as rs537148295, COSV55961411; called by muse, mutect2, varscan2
- LHFPL5 | c.66G>A p.S22= | Silent (SNP) | VAF 32/172 reads (19%) | catalogued as rs771797911, COSV64178346; called by muse, mutect2, varscan2
- LRRC36 | c.1350G>A p.L450= | Silent (SNP) | VAF 45/117 reads (38%) | catalogued as COSV99339073; called by muse, mutect2, varscan2
- MARK4 | c.1068G>A p.K356= | Silent (SNP) | VAF 80/222 reads (36%) | catalogued as rs779872451, COSV99488768; called by muse, mutect2, varscan2
- MED1 | c.4431G>A p.Q1477= | Silent (SNP) | VAF 29/138 reads (21%) | catalogued as COSV100328132, COSV100328141; called by muse, mutect2, varscan2
- MED12L | c.2370C>G p.L790= | Silent (SNP) | VAF 32/99 reads (32%) | catalogued as COSV56389911; called by muse, mutect2, varscan2
- MED12L | c.2826C>T p.L942= | Silent (SNP) | VAF 71/255 reads (28%) | catalogued as COSV99854516; called by muse, mutect2, varscan2
- MFSD6 | c.2106C>G p.L702= | Silent (SNP) | VAF 33/61 reads (54%) | catalogued as COSV99855379; called by muse, mutect2, varscan2
- MICAL2 | c.1962C>G p.L654= | Silent (SNP) | VAF 19/28 reads (68%) | catalogued as COSV56318370; called by muse, mutect2, varscan2
- MINDY1 | c.684C>G p.V228= | Silent (SNP) | VAF 47/167 reads (28%) | catalogued as COSV56498150, COSV56500555; called by muse, mutect2, varscan2
- MOB1B | c.234C>T p.F78= | Silent (SNP) | VAF 3/41 reads (7%) | catalogued as rs1469343856, COSV100511647; called by muse, mutect2
- NCAN | c.3588C>T p.N1196= | Silent (SNP) | VAF 24/85 reads (28%) | catalogued as rs761753453, COSV53053474; called by muse, mutect2, varscan2
- NSMAF | c.597A>G p.K199= | Silent (SNP) | VAF 65/99 reads (66%) | catalogued as COSV99233402; called by muse, mutect2, varscan2
- NTRK2 | c.2418C>G p.L806= (on ENST00000323115 / NM_001369534.1; = p.L822= on NM_006180.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 97/115 reads (84%) | catalogued as COSV99458317; called by muse, mutect2, varscan2
- OR14A16 | c.186G>A p.K62= | Silent (SNP) | VAF 23/90 reads (26%) | catalogued as rs774862927, COSV62926299, COSV62926611; called by muse, mutect2, varscan2
- OR1A2 | c.531C>T p.F177= | Silent (SNP) | VAF 63/165 reads (38%) | catalogued as COSV101126385; called by muse, mutect2, varscan2
- OR1B1 | c.225A>C p.L75= | Silent (SNP) | VAF 50/60 reads (83%) | catalogued as COSV100506542; called by muse, mutect2, varscan2
- OR52B2 | c.123C>T p.V41= | Silent (SNP) | VAF 36/57 reads (63%) | catalogued as COSV101603957, COSV101603963; called by muse, mutect2, varscan2
- OR6N1 | c.855C>T p.L285= | Silent (SNP) | VAF 81/286 reads (28%) | catalogued as rs370643310, COSV100625291; called by muse, mutect2, varscan2
- PDE4A | c.1749C>A p.L583= (on ENST00000380702 / NM_001111307.2; = p.L344= on NM_006202.3) | Silent (SNP) | VAF 39/111 reads (35%) | catalogued as COSV99535095; called by muse, mutect2, varscan2
- PDK1 | c.516C>G p.V172= | Silent (SNP) | VAF 28/90 reads (31%) | catalogued as COSV99961473; called by muse, mutect2, varscan2
- PDS5A | c.231C>T p.F77= | Silent (SNP) | VAF 37/74 reads (50%) | catalogued as COSV100337542; called by muse, mutect2, varscan2
- PIAS3 | c.1038G>T p.L346= | Silent (SNP) | VAF 94/171 reads (55%) | catalogued as COSV100566852; called by muse, mutect2, varscan2
- PLVAP | c.309G>C p.L103= | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as COSV53087671, COSV99391821; called by muse, mutect2, varscan2
- PPP2R3B | c.1374G>C p.L458= | Silent (SNP) | VAF 32/155 reads (21%) | catalogued as COSV101180789; called by muse, mutect2, varscan2
- PPP6R2 | c.579G>A p.Q193= | Silent (SNP) | VAF 11/104 reads (11%) | catalogued as COSV99324768; called by muse, mutect2, varscan2
- RAC2 | c.60C>T p.L20= | Silent (SNP) | VAF 61/145 reads (42%) | catalogued as rs767941433, COSV99969652; called by muse, mutect2, varscan2
- RASGRP2 | c.486C>A p.L162= | Silent (SNP) | VAF 12/101 reads (12%) | catalogued as COSV100818342; called by muse, mutect2, varscan2
- RLF | c.180G>A p.L60= | Silent (SNP) | VAF 37/85 reads (44%) | catalogued as COSV101035677; called by muse, mutect2, varscan2
- RNF208 | c.756G>A p.R252= | Silent (SNP) | VAF 19/29 reads (66%) | catalogued as COSV100763187; called by muse, mutect2, varscan2
- RNFT2 | c.825C>T p.I275= | Silent (SNP) | VAF 63/153 reads (41%) | catalogued as rs768889201, COSV99985209; called by muse, mutect2, varscan2
- SF1 | c.1398A>G p.G466= | Silent (SNP) | VAF 47/117 reads (40%) | catalogued as COSV99918744; called by muse, mutect2, varscan2
- SLC34A2 | c.801C>T p.I267= | Silent (SNP) | VAF 82/126 reads (65%) | catalogued as COSV101158453; called by muse, mutect2, varscan2
- SLC5A3 | c.399C>G p.L133= | Silent (SNP) | VAF 103/292 reads (35%) | catalogued as COSV62970391; called by muse, mutect2, varscan2
- SLMAP | c.66C>T p.V22= | Silent (SNP) | VAF 29/39 reads (74%) | catalogued as COSV99909194; called by muse, mutect2, varscan2
- SOGA1 | c.1764G>A p.K588= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV99415130; called by muse, mutect2, varscan2
- STAM | c.612C>T p.L204= | Silent (SNP) | VAF 36/94 reads (38%) | catalogued as COSV101092383; called by muse, mutect2, varscan2
- TBX19 | c.1080C>T p.S360= | Silent (SNP) | VAF 40/134 reads (30%) | catalogued as rs1479484591, COSV100892405; called by muse, mutect2, varscan2
- TENT5C | c.84C>A p.V28= | Silent (SNP) | VAF 15/87 reads (17%) | catalogued as COSV101033101; called by muse, mutect2, varscan2
- TMEM40 | c.678G>T p.L226= | Silent (SNP) | VAF 10/94 reads (11%) | catalogued as COSV99277304; called by muse, mutect2
- TNFRSF12A | c.270C>T p.F90= | Silent (SNP) | VAF 32/79 reads (41%) | catalogued as rs372932532; called by muse, mutect2, varscan2
- TSHR | c.2239C>T p.L747= | Silent (SNP) | VAF 44/113 reads (39%) | catalogued as rs1397789014, COSV99991082, COSV99992720; called by muse, mutect2, varscan2
- UHRF1BP1 | c.3654G>A p.E1218= | Silent (SNP) | VAF 42/136 reads (31%) | catalogued as COSV99512426; called by muse, mutect2, varscan2
- UMODL1 | c.1743C>T p.L581= | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as rs778641009, COSV61160431; called by muse, mutect2, varscan2
- UPF2 | c.1122C>G p.L374= | Silent (SNP) | VAF 42/88 reads (48%) | catalogued as COSV62661265; called by muse, mutect2, varscan2
- UROC1 | c.981C>T p.H327= | Silent (SNP) | VAF 25/66 reads (38%) | catalogued as rs745678535, COSV99332299; ClinVar: likely benign; called by muse, mutect2, varscan2
- VIPR2 | c.1185G>C p.P395= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV100056405, COSV100058127, COSV51108729; called by muse, mutect2
- YEATS2 | c.2562C>T p.L854= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as COSV100528261, COSV59365408; called by muse, mutect2, varscan2
- ZBTB38 | c.294C>G p.V98= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as COSV100375976; called by muse, mutect2, varscan2
- ZFP36 | c.246C>T p.F82= (on ENST00000594442; = p.F76= on NM_003407.5) | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as rs1361442372, COSV50527908, COSV99953984; called by muse, mutect2, varscan2
- ZNF697 | c.1422C>T p.F474= | Silent (SNP) | VAF 14/25 reads (56%) | catalogued as COSV101360307; called by muse, varscan2
- GCNT2 | c.925+26743C>T | Intron (SNP) | VAF 50/82 reads (61%) | catalogued as COSV100297396; called by muse, mutect2, varscan2
- MFSD12 | chr19:3542798 C>G | 3'Flank (SNP) | VAF 11/31 reads (35%) | catalogued as rs1316263771, COSV100281518; called by muse, mutect2
- NDUFV3 | c.170-4735G>C | Intron (SNP) | VAF 25/66 reads (38%) | catalogued as COSV100447145; called by muse, mutect2, varscan2
- SETD3 | c.849+2778G>C | Intron (SNP) | VAF 44/107 reads (41%) | catalogued as COSV100075437; called by muse, mutect2, varscan2
